Somatic mutation profile of tumor specimen MMRF_2538_1_BM_CD138pos (aliquot MMRF_2538_1_BM_CD138pos_T1_KHS5U_L12837) from MMRF case MMRF_2538, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.5 years (25,037 days).
Specimen MMRF_2538_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 872a2bc2-dc8a-454e-8a78-590bf717e175.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2538_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2538_1_PB_Whole_C3_KHS5U_L12838; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77bec40e-f5ad-4f44-bd06-225a669eecb2

The open-access MAF lists 68 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 20, Silent 8, 5'Flank 3, 5'UTR 2, Nonsense Mutation 1, Frame Shift Ins 1, 3'Flank 1, Intron 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP10B | c.2566C>T p.R856W | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749983555; called by muse, mutect2, varscan2
- CDH23 | c.6547G>A p.V2183M | Missense Mutation (SNP) | VAF 189/383 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs370794439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN5 | c.2657G>A p.S886N | Missense Mutation (SNP) | VAF 252/493 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV54357024; called by muse, mutect2, varscan2
- CYTH1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV63124853; called by muse, mutect2, varscan2
- DACH2 | c.1580G>T p.R527I | Missense Mutation (SNP) | VAF 100/102 reads (98%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV64165399; called by muse, mutect2, varscan2
- HSPG2 | c.5134C>T p.R1712C | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375031442; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.193); catalogued as COSV56269547; called by muse, mutect2
- LTBP2 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs373985419; called by muse, mutect2, varscan2
- MEGF6 | c.3803C>T p.A1268V | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs376256783; called by muse, mutect2, varscan2
- OR51S1 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV59057956, COSV59059204; called by muse, varscan2
- PRKD2 | c.2282T>C p.I761T | Missense Mutation (SNP) | VAF 240/253 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99353977; called by muse, mutect2, varscan2
- RYR2 | c.4268C>T p.T1423M | Missense Mutation (SNP) | VAF 161/332 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as rs534750117, COSV100769422; called by muse, mutect2, varscan2
- SKIL | c.709C>G p.R237G | Missense Mutation (SNP) | VAF 168/382 reads (44%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.816); catalogued as rs367787976, COSV52060695; called by muse, mutect2, varscan2
- TRIT1 | c.596A>G p.H199R | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs760045849; called by muse, mutect2, varscan2
- ANO3 | c.1309A>T p.T437S | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CACNA2D1 | c.815T>A p.I272N | Missense Mutation (SNP) | VAF 111/254 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CFHR5 | c.584C>A p.S195* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | called by muse, mutect2, varscan2
- CNBP | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.447); called by muse, mutect2
- COL22A1 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP2S1 | c.1114C>G p.P372A | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DPP8 | c.2339del p.P780Qfs*29 (on ENST00000341861 / NM_001320875.2; = p.P664Qfs*29 on NM_017743.6) | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | called by mutect2, pindel, varscan2
- EPYC | c.854C>A p.T285N | Missense Mutation (SNP) | VAF 119/246 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FRYL | c.989dup p.L330Ffs*3 | Frame Shift Ins (INS) | VAF 33/63 reads (52%) | called by mutect2, varscan2
- H4C12 | c.43G>C p.G15R | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- HHLA1 | c.1523A>T p.Q508L | Missense Mutation (SNP) | VAF 25/316 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2
- MMACHC | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 171/369 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- NAPA | c.477-3C>T | Splice Region (SNP) | VAF 225/225 reads (100%) | called by muse, mutect2, varscan2
- NRK | c.4716A>T p.K1572N | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRMT9 | c.637T>A p.Y213N | Missense Mutation (SNP) | VAF 135/347 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- RPN1 | c.1732A>C p.K578Q | Missense Mutation (SNP) | VAF 150/298 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.066); called by muse, varscan2
- RTCB | c.265C>A p.H89N | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTC1 | c.858A>C p.Q286H | Missense Mutation (SNP) | VAF 13/271 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF541 | c.3281G>T p.S1094I | Missense Mutation (SNP) | VAF 72/74 reads (97%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CAPSL | c.597C>A p.I199= | Silent (SNP) | VAF 14/317 reads (4%) | called by muse, mutect2
- IGHV2-70 | c.75G>A p.E25= | Silent (SNP) | VAF 52/126 reads (41%) | catalogued as rs181122105; called by muse, varscan2
- KRT24 | c.1275C>T p.N425= | Silent (SNP) | VAF 85/180 reads (47%) | catalogued as rs139679856; called by muse, mutect2, varscan2
- NT5M | c.82C>T p.L28= | Silent (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- PIGK | c.336G>A p.V112= | Silent (SNP) | VAF 62/145 reads (43%) | called by muse, mutect2, varscan2
- SRRM2 | c.3186A>G p.Q1062= | Silent (SNP) | VAF 13/238 reads (5%) | catalogued as rs749401050, COSV57081113; called by muse, mutect2
- SYNGR4 | c.28C>T p.L10= | Silent (SNP) | VAF 69/166 reads (42%) | catalogued as COSV99507470; called by muse, mutect2, varscan2
- ZNF805 | c.309T>G p.S103= | Silent (SNP) | VAF 120/252 reads (48%) | called by muse, mutect2, varscan2
- ACSL3 | c.*146A>G | 3'UTR (SNP) | VAF 7/116 reads (6%) | catalogued as rs868709613; called by muse, mutect2
- ACTN1 | c.*191A>G | 3'UTR (SNP) | VAF 16/26 reads (62%) | called by muse, mutect2, varscan2
- AMER3 | c.*197C>A | 3'UTR (SNP) | VAF 104/233 reads (45%) | catalogued as COSV100366246; called by muse, mutect2, varscan2
- ANKRD28 | c.*2636A>G | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- COL4A3 | c.*682G>T | 3'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- CRB3 | c.-49C>T | 5'UTR (SNP) | VAF 9/17 reads (53%) | catalogued as rs745892441; called by muse, varscan2
- DCAF4 | c.1294+324C>T | Intron (SNP) | VAF 66/151 reads (44%) | catalogued as rs550983298; called by muse, mutect2, varscan2
- EPG5 | c.*1706G>T | 3'UTR (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- ERBIN | c.*2726A>C | 3'UTR (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2, varscan2
- FSD2 | c.*3146C>T | 3'UTR (SNP) | VAF 28/104 reads (27%) | called by muse, mutect2, varscan2
- HSPA12B | c.*838A>C | 3'UTR (SNP) | VAF 54/62 reads (87%) | called by muse, mutect2, varscan2
- HSPA6 | c.*175G>T | 3'UTR (SNP) | VAF 11/268 reads (4%) | called by muse, mutect2
- KLHL30 | c.*275C>A | 3'UTR (SNP) | VAF 56/109 reads (51%) | called by muse, mutect2, varscan2
- LRRC47 | c.*769C>T | 3'UTR (SNP) | VAF 134/271 reads (49%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851221 T>G | 5'Flank (SNP) | VAF 129/285 reads (45%) | catalogued as rs574198295; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851408 G>A | 5'Flank (SNP) | VAF 110/215 reads (51%) | catalogued as rs536974872; called by muse, mutect2, varscan2
- PCLO | c.*276C>A | 3'UTR (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- PCLO | c.*275A>G | 3'UTR (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- PPP4R2 | c.*3296T>C | 3'UTR (SNP) | VAF 7/81 reads (9%) | catalogued as rs1240138536; called by muse, mutect2
- SFRP1 | c.-180C>T | 5'UTR (SNP) | VAF 11/38 reads (29%) | called by mutect2, varscan2
- SLC17A6 | c.*624A>G | 3'UTR (SNP) | VAF 50/106 reads (47%) | called by muse, mutect2, varscan2
- SREBF2 | c.*1405G>C | 3'UTR (SNP) | VAF 46/89 reads (52%) | called by muse, mutect2, varscan2
- STC1 | c.*1538C>A | 3'UTR (SNP) | VAF 50/96 reads (52%) | catalogued as rs912782740; called by muse, mutect2, varscan2
- STEAP4 | c.*4753A>G | 3'UTR (SNP) | VAF 13/236 reads (6%) | called by muse, mutect2
- SYNCRIP | chr6:85611616 T>A | 3'Flank (SNP) | VAF 38/74 reads (51%) | catalogued as rs1023775050, COSV100783988; called by muse, mutect2, varscan2
- WWC2 | chr4:183098647 G>T | 5'Flank (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- ZNF536 | c.*17C>T | 3'UTR (SNP) | VAF 121/262 reads (46%) | catalogued as rs761127143, COSV100835028; called by muse, mutect2, varscan2
